Somatic mutation profile of tumor specimen TCGA-A7-A0DB-01A (aliquot TCGA-A7-A0DB-01A-11D-A272-09) from TCGA case TCGA-A7-A0DB, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 56.3 years (20,570 days).
Specimen TCGA-A7-A0DB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d577f725-e910-4a77-89e9-2e982d5493e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A0DB-10A (Blood Derived Normal), aliquot TCGA-A7-A0DB-10A-02D-A272-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8976db3-5077-4b8f-9d6c-41a562ae1b4c

The open-access MAF lists 43 somatic variants for this specimen: 28 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 14, Frame Shift Ins 2, Nonsense Mutation 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 5/54 reads (9%) | catalogued as COSV100857074; called by muse, mutect2
- ADNP2 | c.1790C>G p.S597C | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV51541989; called by muse, mutect2
- BDP1 | c.1183A>G p.K395E | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1285423349, COSV62434163; called by muse, mutect2
- CCKBR | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs749874540, COSV58100133; called by muse, mutect2, varscan2
- CD163L1 | c.2926C>A p.L976M | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.591); catalogued as COSV58010744, COSV58023412; called by muse, mutect2, varscan2
- CEACAM20 | c.1740G>C p.E580D | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.113); catalogued as COSV57603084; called by muse, mutect2, varscan2
- DZIP3 | c.2740G>T p.A914S | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100848114; called by muse, mutect2
- FBN3 | c.8236G>A p.E2746K | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs780590806, COSV53664292; called by muse, mutect2, varscan2
- HEATR1 | c.6345A>C p.E2115D | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59382639; called by muse, mutect2, varscan2
- LRRC14 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.3); catalogued as rs755544856, COSV52881678; called by muse, mutect2, varscan2
- MTCL1 | c.4171G>A p.E1391K (on ENST00000306329 / NM_001378206.1; = p.E1072K on NM_015210.4) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60410985; called by muse, mutect2, varscan2
- OPLAH | c.3411C>A p.H1137Q | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as COSV101470967; called by muse, mutect2
- PDHA1 | c.57G>A p.P19= | Splice Region (SNP) | VAF 9/19 reads (47%) | catalogued as COSV63329015; called by muse, mutect2, varscan2
- PEDS1-UBE2V1 | c.910T>G p.F304V | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.135); catalogued as rs761220005, COSV59015503; called by muse, mutect2, varscan2
- QRICH2 | c.3416T>A p.I1139K | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99429804; called by muse, mutect2
- SCN2A | c.5632C>A p.Q1878K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV51853394; called by muse, mutect2, varscan2
- SLC9A2 | c.1390G>T p.A464S | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as COSV52136935; called by muse, mutect2, varscan2
- SYNE2 | c.1818G>C p.K606N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV59967069; called by muse, mutect2
- SYNE2 | c.12647C>G p.S4216C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.41); catalogued as COSV59967077; called by muse, mutect2, varscan2
- USHBP1 | c.1884G>C p.Q628H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV53105890; called by muse, mutect2, varscan2
- WNK1 | c.5356C>G p.L1786V (on ENST00000315939 / NM_018979.4; = p.L1539V on NM_014823.3) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); catalogued as COSV60043672; called by muse, mutect2
- WNT5B | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV60198884; called by muse, mutect2, varscan2
- YLPM1 | c.5716G>C p.E1906Q | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53119378; called by muse, mutect2, varscan2
- ZNF432 | c.1407G>C p.K469N | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.907); catalogued as COSV55418199; called by muse, mutect2, varscan2
- ZNF506 | c.233A>G p.Y78C | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71354659; called by muse, mutect2, varscan2
- MAP3K1 | c.1368dup p.T457Yfs*4 | Frame Shift Ins (INS) | VAF 10/28 reads (36%) | called by mutect2, varscan2
- MAP3K1 | c.2012_2013dup p.E672Rfs*14 | Frame Shift Ins (INS) | VAF 10/36 reads (28%) | called by mutect2, varscan2
- ATG9B | c.879G>T p.L293= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV65059494; called by muse, mutect2
- FOXD4L5 | c.411C>T p.F137= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV66241137; called by mutect2, varscan2
- GRN | c.1143C>T p.L381= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99275169; called by muse, mutect2, varscan2
- H2AC12 | c.360G>A p.K120= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as rs766851091, COSV63617147; called by muse, mutect2, varscan2
- LCE3D | c.237C>T p.G79= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as rs61745173, COSV64230550; called by muse, mutect2, varscan2
- LSMEM1 | c.108C>G p.A36= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV57197070; called by muse, varscan2
- MGAT4B | c.597C>T p.I199= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as COSV99482453; called by muse, mutect2
- NGEF | c.24T>C p.D8= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV50948845; called by muse, mutect2, varscan2
- NUDT11 | c.345G>A p.R115= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as COSV65665447; called by muse, mutect2, varscan2
- NUDT6 | c.906T>C p.H302= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV52652584; called by muse, mutect2, varscan2
- SPTA1 | c.4998G>A p.L1666= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV63758246; called by muse, mutect2
- TANC2 | c.759A>G p.Q253= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as rs1415799490, COSV67340455; called by muse, mutect2, varscan2
- TRAPPC9 | c.2439C>T p.I813= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs769157936, COSV101228518; called by muse, mutect2
- ZNF749 | c.1977G>A p.Q659= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV61947981; called by muse, mutect2, varscan2
- C8orf31 | n.634C>T | RNA (SNP) | VAF 6/30 reads (20%) | catalogued as rs371078298; called by muse, mutect2, varscan2
